Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A710, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A710-01A (Primary Tumor).

[page 1 of 3]
Specimen Description

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

--- Clinical History ---
Frontal temporal parietal lesion.

ADDENDA:
Addendum added: [REDACTED]

---Final Pathologic Diagnosis---

- A. Left frontal tumor, excision:
- Oligodendroglioma (WHO grade II). See comment.
- B. Left frontal tumor, excision:
- Oligodendroglioma (WHO grade II).

Comment: The overall profile is that of a low grade oligodendroglioma. However, focally elevated proliferation index of about 8-10% raises the possibility of future biological progression to higher grade. Closer follow up is recommended.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the [REDACTED] laboratories in the [REDACTED] and are not required to have nor do they have FDA approval.

---Electronically Signed By---

---Addendum Report---

Addendum

Status: Signed Out

Detection of 1p36 and 19q by 1p36/ 1q25 and 19q13/19p13
Dual-Color Probe Sets

Oligodendroglioma grade II
9450/3
Sate CCLF NDS
Brain, supratentorial
C71.0
path
Brain, frontal lobe
C71.1
9/8/22/13

[page 2 of 3]
[REDACTED]

Case No [REDACTED] Patient Name:
Pathologist [REDACTED]
Source of case [REDACTED] Patient MRN:
Block used B2
Tissue fixation formalin-fixed tissue
Tissue source Brain

RESULTS

Ratio of 1p/1q 0.35 Cell count of 1p/1q: 109
Ratio of 19q/19p 0.37 Cell count of 19q/19p: 111
Interpretation of Results: A) 1p loss; B) 19q loss
Interpretation of findings:
A) (positive) The majority of tumors cells displayed 2 control chromosome 1q25 signals and 1 chromosome 1p36 signals (locus of interest). The ratio of 1p36/1q25 is <0.8 . The results are consistent with the loss of 1p36 locus of interest. B) (positive) The majority of tumors cells displayed 2 control chromosome 19p13 signals and 1 chromosome 19q13 signals (locus of interest). The ratio of 19q13/19p13 is <0.8 . The results are consistent with the loss of 1p36 locus of interest.

Number of Observers: 2

Test Interpreted By: [REDACTED]

Comments

The resultant FISH section/slide is scanned by a trained licensed medical technologist and analyzed using a FDA-approved, validated semi-automated scanning imaging workstation and accompanying imaging analysis software. The resultant FISH section/slide is then presented to the interpreting Pathologist, who will reviews the FISH results from and compares them to the results manually observed under Fluorescence Microscope. Therefore the ratio is enumerated by computer-aided counting as well as manual counting.

Interpretation of Test

The ratio for probe set 1 is derived by dividing the total number of 1p36 signals by the total number of 1q25 signals in at least 20 interphase nuclei with nonoverlapping nuclei in the neoplastic glial cells. Cells with no signals or with signals of only one color are disregarded. The ratio for probe set 2 is derived by dividing the total number of 19q13 signals by the total number of 19p13 signals in at least 2 sets of 20 interphase nuclei with nonoverlapping nuclei in the neoplastic glial cells at two different areas of the sample. Cells with no signals or with signals of only one color are disregarded. Reference ranges for our laboratory for allelic loss versus no allelic loss were established by evaluating both probe sets in a series of 40 normal cases from 10 different organs. For both probe set 1 and 2 a ratio of less than 0.80 taken from at least 2 sets of 20 interphase nuclei at 2 different areas with nonoverlapping nuclei is consistent with allelic loss. FISH and H&E stained slides have been reviewed by the interpreting pathologist.

Limitations

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

[page 3 of 3]
---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Left frontal tumor: (FROZEN SECTION PERFORMED)
Infiltrating glioma.

Examining pathologist

---MICROSCOPIC:---

Sections show a mild to focally moderately cellular neoplasm infiltrative into the gray and white matter. The cells display round to ovoid nuclear configuration. Prominent perinuclear halos and background slender vasculature are present. Rare mitotic figures are seen. Immunostain for GFAP is positive in a small number of cells and a KI-67 stain shows focal elevation of proliferation index to about 8-10% (as determined by manual immunohistochemistry method).

---SPECIMEN(S) RECEIVED:---

A: Brain BX
B: Brain Reg

---GROSS DESCRIPTION:---

The specimens are received in two properly labeled containers with the patient's name and accession number, one of which is submitted to frozen section.

A. The specimen is designated "left frontal tumor" and consists of two portions of tan soft tissue measuring 0.8 x 0.3 x 0.2 cm in aggregate. A touch prep was made, and a larger tissue portion was submitted for frozen section. Frozen section cassette AF1 is resubmitted as received. The remainder of the specimen is submitted in A1.

B. The specimen is designated "left frontal tumor" and consists of a 4.49 gram, 2.8 x 2.1 x 1.7 cm portion of gray-white, soft, slightly friable soft tissue. The cut surfaces are smooth and appear grossly unremarkable.

Lab Use Only:

Gross description by:

Source: NCI Genomic Data Commons file 9b199ccb-8955-4a33-8924-15250d2fdc9f (TCGA-FG-A710.0D50F154-43CC-4916-9D8E-A5C16F626971.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).